Somatic mutation profile of tumor specimen MMRF_1546_1_BM_CD138pos (aliquot MMRF_1546_1_BM_CD138pos_T1_KHS5U_L12848) from MMRF case MMRF_1546, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.8 years (24,752 days).
Specimen MMRF_1546_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30f8c023-f2c6-45bd-b769-ceb761655d63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1546_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1546_1_PB_Whole_C3_KHS5U_L12847; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84d30201-b3c4-4877-840a-f01afddd0959

The open-access MAF lists 91 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 20, Silent 13, Intron 8, Nonsense Mutation 5, 5'Flank 4, 5'UTR 3, RNA 2, 3'Flank 2, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 62/153 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ADAMTS14 | c.2791C>T p.R931W | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200901270, COSV64603831; called by muse, mutect2, varscan2
- ADAMTS2 | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.757); catalogued as COSV51090486; called by muse, mutect2
- ANO10 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769678648, COSV52730019; called by muse, mutect2, varscan2
- CBX7 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs1318525216; called by muse, mutect2, varscan2
- COL1A1 | c.2632G>A p.G878S | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72653146, CM070757; called by muse, mutect2, varscan2
- F13B | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 65/103 reads (63%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.51); catalogued as rs1183360497, COSV66372502; called by muse, mutect2, varscan2
- GPR137 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs909951119, COSV57401840; called by muse, mutect2, varscan2
- HACD4 | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 69/314 reads (22%) | catalogued as rs1258563536; called by muse, mutect2, varscan2
- IGHJ5 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 26/40 reads (65%) | PolyPhen benign (0.001); catalogued as rs782494105; called by muse, varscan2
- IGHV2-70 | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 38/58 reads (66%) | catalogued as rs370713802; called by muse, varscan2
- IGLL5 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs560170702; called by muse, varscan2
- KIF12 | c.1435G>A p.G479S (on ENST00000640217; = p.G341S on NM_138424.1) | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.012); catalogued as rs762397655; called by muse, mutect2, varscan2
- LRRIQ3 | c.103T>G p.F35V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV63051299; called by muse, mutect2, varscan2
- MYO16 | c.1685G>A p.C562Y | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51785249; called by muse, mutect2, varscan2
- NEU1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as rs779431356, COSV57669330; called by muse, mutect2, varscan2
- NLRP14 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs772258317; called by muse, mutect2, varscan2
- RELN | c.989A>G p.Q330R | Missense Mutation (SNP) | VAF 188/326 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100634447; called by muse, mutect2, varscan2
- SLC15A1 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as rs1442481002; called by muse, mutect2, varscan2
- SYNDIG1 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs370102448; called by muse, mutect2, varscan2
- TAPT1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs1482999645; called by muse, mutect2, varscan2
- AC098582.1 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2
- ADRA1A | c.883G>T p.G295W | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASIC2 | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- DOCK1 | c.2072T>G p.F691C | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGR1 | c.181A>T p.N61Y | Missense Mutation (SNP) | VAF 93/236 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); called by muse, varscan2
- EGR1 | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.352); called by muse, varscan2
- FER1L5 | c.633+4G>A | Splice Region (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- GAPVD1 | c.2383G>A p.G795S | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- H1-0 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- IGHV2-70D | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- IGHV2-70D | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, varscan2
- NEK10 | c.408A>C p.L136F | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- OR10W1 | c.353G>T p.C118F | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- PDGFRA | c.49+1G>C p.X17_splice | Splice Site (SNP) | VAF 90/277 reads (32%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.4168A>G p.T1390A | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENT5C | c.286del p.H96Mfs*22 | Frame Shift Del (DEL) | VAF 56/148 reads (38%) | called by mutect2, pindel, varscan2
- TMIGD2 | c.267G>A p.W89* | Nonsense Mutation (SNP) | VAF 54/157 reads (34%) | called by muse, mutect2, varscan2
- ZAN | c.4485G>A p.W1495* | Nonsense Mutation (SNP) | VAF 52/178 reads (29%) | called by muse, mutect2, varscan2
- CAND2 | c.1788C>T p.G596= (on ENST00000456430 / NM_001162499.2; = p.G503= on NM_012298.3) | Silent (SNP) | VAF 154/247 reads (62%) | catalogued as rs776303273, COSV55988089; called by muse, mutect2, varscan2
- CNTNAP2 | c.1032C>T p.G344= | Silent (SNP) | VAF 65/262 reads (25%) | catalogued as rs142122012, COSV62145397; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- COL19A1 | c.3150C>T p.A1050= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs1480549789, COSV59572048; called by muse, mutect2, varscan2
- CYFIP1 | c.3264C>T p.C1088= | Silent (SNP) | VAF 139/263 reads (53%) | catalogued as rs139766894; called by muse, mutect2, varscan2
- GRM8 | c.387G>A p.S129= | Silent (SNP) | VAF 152/261 reads (58%) | catalogued as rs781101693, COSV58836897; called by muse, mutect2, varscan2
- IGLL5 | c.84G>A p.L28= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs772288552, COSV73248990, COSV73251143; called by muse, varscan2
- LRCH3 | c.699C>A p.I233= | Silent (SNP) | VAF 95/370 reads (26%) | called by muse, varscan2
- NLGN2 | c.1227T>A p.T409= | Silent (SNP) | VAF 133/456 reads (29%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.1845C>T p.S615= (on ENST00000400915 / NM_001042663.3; = p.S578= on NM_020631.6) | Silent (SNP) | VAF 60/169 reads (36%) | catalogued as rs780943329; called by muse, mutect2, varscan2
- PTPRJ | c.3930C>A p.I1310= | Silent (SNP) | VAF 131/401 reads (33%) | called by muse, mutect2, varscan2
- SBNO2 | c.3276G>A p.T1092= | Silent (SNP) | VAF 117/473 reads (25%) | catalogued as rs758034628; called by muse, mutect2, varscan2
- SLC6A3 | c.21C>T p.S7= | Silent (SNP) | VAF 17/323 reads (5%) | catalogued as rs555623170; called by muse, mutect2
- VPS37B | c.468C>A p.I156= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV53440724; called by muse, mutect2, varscan2
- ADGRL1 | c.1630-62G>A | Intron (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- C17orf49 | c.117-51C>T | Intron (SNP) | VAF 24/81 reads (30%) | catalogued as rs759161458; called by muse, mutect2, varscan2
- C1QTNF3 | c.*949C>T | 3'UTR (SNP) | VAF 26/145 reads (18%) | called by muse, mutect2, varscan2
- CD163L1 | c.4184-173A>G | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, varscan2
- CD3E | c.*111C>G | 3'UTR (SNP) | VAF 47/113 reads (42%) | called by muse, mutect2, varscan2
- CHMP5 | c.*286A>C | 3'UTR (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- CHRM2 | chr7:137018759 del AG | 3'Flank (DEL) | VAF 30/132 reads (23%) | called by mutect2, pindel, varscan2
- CROCCP2 | n.2228C>T | RNA (SNP) | VAF 3/17 reads (18%) | catalogued as rs1271113848; called by muse, mutect2
- DNAJB6 | c.898+124G>A | Intron (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- ENPP1 | c.*187C>A | 3'UTR (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2, varscan2
- ENY2 | c.155-25G>T | Intron (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- EPHA2 | c.*631G>A | 3'UTR (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- ERBB4 | c.*2259G>C | 3'UTR (SNP) | VAF 32/137 reads (23%) | called by muse, mutect2, varscan2
- FRG2EP | n.378C>G | RNA (SNP) | VAF 15/141 reads (11%) | called by muse, mutect2, varscan2
- GBP3 | c.*643C>T | 3'UTR (SNP) | VAF 27/66 reads (41%) | catalogued as rs909228085; called by muse, mutect2, varscan2
- GCLC | chr6:53544801 C>T | 5'Flank (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- HAPLN1 | c.*2519G>A | 3'UTR (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
- HRH1 | c.*143G>T | 3'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- IGF1R | c.*2845T>A | 3'UTR (SNP) | VAF 59/121 reads (49%) | called by muse, mutect2, varscan2
- IGFBP3 | chr7:45921801 G>T | 5'Flank (SNP) | VAF 18/412 reads (4%) | called by muse, mutect2
- INTS7 | c.*598G>A | 3'UTR (SNP) | VAF 34/73 reads (47%) | catalogued as rs1391660902; called by muse, mutect2, varscan2
- OPRM1 | c.-471del | 5'UTR (DEL) | VAF 77/329 reads (23%) | called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.*2430C>T | 3'UTR (SNP) | VAF 37/253 reads (15%) | catalogued as rs754535033; called by muse, mutect2, varscan2
- PNN | c.499-66T>C | Intron (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2
- RC3H1 | c.*2724A>G | 3'UTR (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2, varscan2
- RETREG2 | chr2:219178260 C>A | 5'Flank (SNP) | VAF 5/21 reads (24%) | catalogued as rs570925914; called by muse, mutect2, varscan2
- RORA | c.-75A>G | 5'UTR (SNP) | VAF 36/153 reads (24%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.*800C>A | 3'UTR (SNP) | VAF 45/154 reads (29%) | called by muse, mutect2, varscan2
- SFMBT2 | c.526-404T>G | Intron (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- SPATA24 | chr5:139396728 G>A | 3'Flank (SNP) | VAF 11/266 reads (4%) | called by muse, mutect2
- STXBP2 | c.*52G>C | 3'UTR (SNP) | VAF 15/68 reads (22%) | catalogued as rs758638420; called by muse, mutect2, varscan2
- TMEM26 | c.*64C>G | 3'UTR (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- TNK2 | c.1543+47A>G | Intron (SNP) | VAF 115/207 reads (56%) | called by muse, mutect2
- TWIST2 | c.-123C>T | 5'UTR (SNP) | VAF 32/268 reads (12%) | catalogued as rs1033287091; called by muse, mutect2, varscan2
- WNT9A | c.*2020C>A | 3'UTR (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- XCR1 | c.*3429dup | 3'UTR (INS) | VAF 34/126 reads (27%) | called by mutect2, pindel, varscan2
- XDH | c.*919dup | 3'UTR (INS) | VAF 50/90 reads (56%) | called by mutect2, varscan2
- ZNF280D | chr15:56733710 G>A | 5'Flank (SNP) | VAF 18/39 reads (46%) | catalogued as rs751304444, COSV50997320; called by muse, mutect2, varscan2
- ZNF44 | c.*223A>T | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2
